Somatic mutation profile of tumor specimen C3L-08548-01 (aliquot CPT0478080006) from CPTAC case C3L-08548, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 86.2 years (31,467 days).
Specimen C3L-08548-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f7ee6fa-32e2-4fa8-aacd-8e8ff98fdbfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08548-31 (Blood Derived Normal), aliquot CPT0475800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/760e7c47-1373-4668-acc5-17f705e3338d

The open-access MAF lists 158 somatic variants for this specimen: 102 protein-altering or splice-affecting, 50 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 50, Nonsense Mutation 7, Intron 4, In Frame Del 3, Frame Shift Del 2, 3'UTR 1, RNA 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.1808G>A p.R603H (on ENST00000490131; = p.R680H on NM_000388.4) | Missense Mutation (SNP) | VAF 83/644 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773146939, CM002581; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 94/297 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 65/112 reads (58%) | catalogued as rs377767326, CM064283, COSV61684940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN1 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 165/492 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs371440985, COSV51997373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRB1 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 199/502 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60097540; called by muse, mutect2, varscan2
- ALPG | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 123/653 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.981); catalogued as rs1170586159; called by muse, mutect2, varscan2
- ALS2CL | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769338497; called by muse, mutect2, varscan2
- AXL | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 76/548 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs752081844; called by muse, mutect2, varscan2
- BHLHE41 | c.1230_1232dup p.A411dup | In Frame Ins (INS) | VAF 58/315 reads (18%) | catalogued as rs909227356; called by mutect2, varscan2
- BICRAL | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.109); catalogued as rs1460183073; called by muse, mutect2
- CACNA1A | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs773461333, COSV64215356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.6230G>A p.R2077H (on ENST00000367573 / NM_001205293.3; = p.R2034H on NM_000721.4) | Missense Mutation (SNP) | VAF 152/317 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs759720068, COSV62385287, COSV62397428; called by muse, mutect2, varscan2
- CALN1 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 189/423 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as rs1036919510, COSV67953968; called by muse, mutect2, varscan2
- CPNE1 | c.1559C>T p.P520L (on ENST00000352393; = p.P525L on NM_003915.5) | Missense Mutation (SNP) | VAF 79/554 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs142770190, COSV100467345; called by muse, mutect2, varscan2
- CPNE8 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 178/472 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs145635815, COSV58841994, COSV58845984; called by muse, varscan2
- DCP1B | c.892A>G p.M298V | Missense Mutation (SNP) | VAF 146/543 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs962264666; called by muse, varscan2
- DGKI | c.3016C>T p.R1006W | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs774412671, COSV55936948; called by muse, mutect2, varscan2
- EXOC3L2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 104/899 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.711); catalogued as rs1383514223; called by muse, mutect2, varscan2
- FAM83C | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 467/798 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761100860, COSV65582998; called by muse, mutect2, varscan2
- FAM98C | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 79/593 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs111816359; called by muse, mutect2, varscan2
- HOXD8 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 74/468 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs775144676; called by muse, mutect2, varscan2
- IGHG1 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as rs1392485019; called by muse, mutect2
- IRX1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 717/1096 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV57359485; called by muse, mutect2, varscan2
- KIRREL1 | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 62/451 reads (14%) | catalogued as COSV63287986; called by muse, mutect2, varscan2
- KSR2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 260/576 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs756996528, COSV60370733; called by muse, mutect2, varscan2
- LGR6 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 280/580 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.351); catalogued as rs1195600842; called by muse, mutect2, varscan2
- MAN2B2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs372678222; called by muse, mutect2, varscan2
- MGAT5B | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs144453101; called by muse, mutect2, varscan2
- MTOR | c.5245C>T p.R1749* | Nonsense Mutation (SNP) | VAF 59/209 reads (28%) | catalogued as rs752198342, COSV63878425; called by muse, mutect2, varscan2
- NLRP13 | c.2415G>T p.L805F | Missense Mutation (SNP) | VAF 95/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61621547; called by muse, mutect2, varscan2
- OR2AK2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs371051095; called by muse, mutect2, varscan2
- OR52J3 | c.123G>T p.L41F | Missense Mutation (SNP) | VAF 150/383 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs1012417518; called by muse, mutect2, varscan2
- OXTR | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57479445; called by muse, mutect2, varscan2
- PCDH9 | c.3656T>C p.L1219P (on ENST00000377865 / NM_203487.3; = p.L1185P on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV60536417; called by muse, mutect2, varscan2
- PLXNA3 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 347/490 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781823667; called by muse, mutect2, varscan2
- PRKDC | c.11584G>A p.A3862T | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs568709506, COSV100038676; called by muse, varscan2
- RGPD3 | c.3850C>T p.H1284Y | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1210873660; called by muse, mutect2
- RIMS2 | c.2119C>A p.P707T (on ENST00000666250 / NM_001348490.2; = p.P515T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373650645; called by muse, mutect2, varscan2
- SPATA31D3 | c.2483C>A p.T828K | Missense Mutation (SNP) | VAF 33/375 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100501041; called by muse, mutect2, varscan2
- TIGIT | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 315/567 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs138322602; called by muse, mutect2, varscan2
- TMEM132C | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 122/448 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.423); catalogued as COSV59422797; called by muse, varscan2
- TMEM196 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 243/531 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs372571256; called by muse, mutect2, varscan2
- TNF | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 135/575 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV101403128; called by muse, mutect2, varscan2
- UFSP2 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV52993060; called by muse, mutect2, varscan2
- URAD | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 99/535 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.354); catalogued as rs940213034; called by muse, mutect2, varscan2
- XRRA1 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 64/153 reads (42%) | catalogued as rs1417392893, COSV58496264; called by muse, mutect2, varscan2
- ZMIZ1 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.255); catalogued as COSV57905016; called by muse, mutect2, varscan2
- ZNF229 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 56/395 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.302); catalogued as COSV52164167; called by muse, mutect2, varscan2
- AATK | c.2648G>A p.R883K (on ENST00000326724 / NM_001080395.3; = p.R780K on NM_004920.2) | Missense Mutation (SNP) | VAF 65/462 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL3 | c.369C>A p.C123* | Nonsense Mutation (SNP) | VAF 41/253 reads (16%) | called by muse, mutect2, varscan2
- ADRM1 | c.246del p.F82Lfs*15 | Frame Shift Del (DEL) | VAF 44/345 reads (13%) | called by mutect2, pindel, varscan2
- CACNA1H | c.5239C>A p.P1747T | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNT1 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 182/443 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP152 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 145/235 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- CFAP53 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CPNE8 | c.1666C>A p.P556T | Missense Mutation (SNP) | VAF 50/391 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- CYP3A4 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 45/225 reads (20%) | called by muse, mutect2, varscan2
- DIAPH1 | c.1988T>C p.I663T | Missense Mutation (SNP) | VAF 103/218 reads (47%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DIAPH2 | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- DOCK2 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC2H1 | c.12691C>T p.Q4231* | Nonsense Mutation (SNP) | VAF 55/136 reads (40%) | called by muse, mutect2, varscan2
- FZD8 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- GDF2 | c.1259G>C p.G420A | Missense Mutation (SNP) | VAF 11/351 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- GLI4 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- GNB3 | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 92/344 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- HPDL | c.755A>T p.K252M | Missense Mutation (SNP) | VAF 84/450 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- KPTN | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 128/547 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LIPF | c.1079dup p.N360Kfs*29 | Frame Shift Ins (INS) | VAF 47/265 reads (18%) | called by mutect2, pindel, varscan2
- LYST | c.6074C>T p.T2025I | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEC1 | c.1901C>A p.S634Y | Missense Mutation (SNP) | VAF 304/402 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MUC12 | c.2099del p.G700Afs*224 (on ENST00000379442; = p.G557Afs*224 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 137/1364 reads (10%) | called by mutect2, pindel, varscan2
- MYO5A | c.1789_1791del p.K597del | In Frame Del (DEL) | VAF 158/303 reads (52%) | called by mutect2, pindel, varscan2
- NACAD | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 25/671 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2
- OR5M10 | c.797A>C p.K266T | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- P2RY8 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 110/1187 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- PCDH9 | c.3229G>A p.G1077R (on ENST00000377865 / NM_203487.3; = p.G1043R on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/375 reads (40%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PIF1 | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3CG | c.3021G>T p.Q1007H | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2
- PIK3R4 | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- PPFIA2 | c.3313G>A p.V1105M | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRAMEF14 | c.855A>T p.E285D | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PRUNE2 | c.5900G>A p.C1967Y | Missense Mutation (SNP) | VAF 35/396 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.024); called by muse, mutect2
- REC8 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 124/417 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCN3B | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC4A10 | c.2714G>A p.G905D (on ENST00000446997 / NM_001354461.2; = p.G875D on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/335 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A1 | c.1196G>T p.C399F | Missense Mutation (SNP) | VAF 85/381 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC6A6 | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK6 | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 113/309 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SOX11 | c.1266C>A p.S422R | Missense Mutation (SNP) | VAF 71/568 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STAT1 | c.617T>G p.L206R | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- STAT3 | c.1172_1186del p.T391_N395del | In Frame Del (DEL) | VAF 45/340 reads (13%) | called by mutect2, pindel, varscan2
- TAF1L | c.2551_2553del p.K851del | In Frame Del (DEL) | VAF 56/327 reads (17%) | called by mutect2, pindel, varscan2
- TBC1D16 | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TG | c.5446C>A p.Q1816K | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- THPO | c.968C>A p.P323H (on ENST00000649095 / NM_001290003.1; = p.P183H on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/674 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTN | c.96794C>G p.T32265R (on ENST00000591111; = p.T24841R on NM_003319.4) | Missense Mutation (SNP) | VAF 30/208 reads (14%) | PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- UBTF | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 64/416 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- UNK | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 61/417 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- USP9X | c.7390A>G p.R2464G | Missense Mutation (SNP) | VAF 78/342 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- XRCC6 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ZNF154 | c.1085G>A p.C362Y | Missense Mutation (SNP) | VAF 144/638 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZYG11B | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC068580.4 | c.915G>A p.V305= | Silent (SNP) | VAF 67/418 reads (16%) | called by muse, mutect2, varscan2
- ACTRT2 | c.477C>T p.S159= | Silent (SNP) | VAF 185/450 reads (41%) | catalogued as rs146343684; called by muse, mutect2, varscan2
- ADAMTS19 | c.702G>A p.R234= | Silent (SNP) | VAF 205/413 reads (50%) | called by muse, mutect2, varscan2
- ANK2 | c.6843G>A p.T2281= | Silent (SNP) | VAF 142/342 reads (42%) | catalogued as rs548896674; called by muse, mutect2, varscan2
- BMP8A | c.453G>T p.V151= | Silent (SNP) | VAF 28/244 reads (11%) | called by muse, mutect2, varscan2
- CACNA1A | c.3933C>T p.Y1311= | Silent (SNP) | VAF 120/253 reads (47%) | called by muse, mutect2, varscan2
- CEBPA | c.717C>T p.P239= | Silent (SNP) | VAF 304/663 reads (46%) | called by muse, mutect2, varscan2
- CYP27B1 | c.216C>T p.F72= | Silent (SNP) | VAF 149/542 reads (27%) | catalogued as rs565490799; called by muse, mutect2, varscan2
- CYP2D6 | c.258C>T p.A86= | Silent (SNP) | VAF 235/988 reads (24%) | called by muse, mutect2, varscan2
- EEF2K | c.1167C>T p.T389= | Silent (SNP) | VAF 259/513 reads (50%) | catalogued as COSV53781945; called by muse, mutect2, varscan2
- ENPEP | c.1047C>T p.I349= | Silent (SNP) | VAF 79/181 reads (44%) | catalogued as rs772359399, COSV99488306; called by muse, mutect2, varscan2
- EPHB6 | c.672C>T p.V224= | Silent (SNP) | VAF 168/508 reads (33%) | catalogued as rs541042559, COSV67419250; called by muse, varscan2
- EYA2 | c.648C>T p.S216= | Silent (SNP) | VAF 73/373 reads (20%) | catalogued as rs367734889; called by muse, mutect2, varscan2
- FAM219A | c.144G>A p.P48= | Silent (SNP) | VAF 44/182 reads (24%) | catalogued as rs749745396; called by muse, mutect2, varscan2
- FGF13 | c.15G>T p.V5= | Silent (SNP) | VAF 183/235 reads (78%) | called by muse, mutect2, varscan2
- GABRA4 | c.645G>A p.P215= | Silent (SNP) | VAF 63/211 reads (30%) | catalogued as rs750342143, COSV51931311; called by muse, mutect2, varscan2
- GATA3 | c.642G>A p.S214= | Silent (SNP) | VAF 106/564 reads (19%) | catalogued as rs1267931578, COSV100651056; called by muse, mutect2, varscan2
- GNS | c.558G>A p.L186= | Silent (SNP) | VAF 30/271 reads (11%) | catalogued as rs200414276; called by muse, mutect2, varscan2
- GPRIN1 | c.2592C>T p.G864= | Silent (SNP) | VAF 102/401 reads (25%) | called by muse, mutect2, varscan2
- IFT122 | c.1443C>T p.G481= (on ENST00000348417 / NM_052989.3; = p.G422= on NM_018262.4) | Silent (SNP) | VAF 56/487 reads (11%) | called by muse, mutect2, varscan2
- IK | c.1470C>T p.S490= | Silent (SNP) | VAF 14/212 reads (7%) | catalogued as rs1344365954, COSV64226251; called by muse, mutect2
- JUNB | c.879C>T p.I293= | Silent (SNP) | VAF 15/468 reads (3%) | catalogued as rs889966481, COSV56878245, COSV56878450; called by muse, mutect2
- KCNG1 | c.111C>T p.G37= | Silent (SNP) | VAF 94/562 reads (17%) | catalogued as rs1263710861; called by muse, mutect2, varscan2
- KCNK6 | c.220C>A p.R74= | Silent (SNP) | VAF 49/1076 reads (5%) | called by muse, mutect2
- KIT | c.15C>T p.R5= | Silent (SNP) | VAF 73/327 reads (22%) | called by muse, mutect2, varscan2
- KLF1 | c.69A>C p.T23= | Silent (SNP) | VAF 54/261 reads (21%) | called by muse, mutect2, varscan2
- KRT81 | c.189C>T p.F63= | Silent (SNP) | VAF 124/566 reads (22%) | called by muse, mutect2, varscan2
- LEPR | c.519T>C p.P173= | Silent (SNP) | VAF 52/134 reads (39%) | catalogued as rs748461173; called by mutect2, varscan2
- LRP3 | c.90C>T p.T30= | Silent (SNP) | VAF 57/575 reads (10%) | catalogued as rs138753598; called by muse, mutect2, varscan2
- MAP10 | c.831C>T p.C277= | Silent (SNP) | VAF 304/560 reads (54%) | catalogued as COSV101406581; called by muse, varscan2
- NLRP4 | c.1074A>G p.G358= | Silent (SNP) | VAF 61/526 reads (12%) | called by muse, mutect2, varscan2
- OR52E2 | c.501G>T p.R167= | Silent (SNP) | VAF 124/265 reads (47%) | called by muse, mutect2, varscan2
- PAN2 | c.2061T>A p.P687= | Silent (SNP) | VAF 66/416 reads (16%) | called by muse, mutect2, varscan2
- PCDH10 | c.1710C>T p.N570= | Silent (SNP) | VAF 15/534 reads (3%) | catalogued as rs1488340834, COSV52088524; called by muse, mutect2
- PDE3A | c.114G>A p.P38= | Silent (SNP) | VAF 304/751 reads (40%) | called by muse, mutect2, varscan2
- PIEZO1 | c.3948C>T p.A1316= | Silent (SNP) | VAF 60/263 reads (23%) | called by muse, mutect2, varscan2
- SALL1 | c.618G>A p.A206= | Silent (SNP) | VAF 95/390 reads (24%) | catalogued as rs773443491, COSV51763550; called by muse, mutect2, varscan2
- SCN3A | c.765G>A p.V255= | Silent (SNP) | VAF 76/273 reads (28%) | called by muse, mutect2, varscan2
- SDK2 | c.87G>A p.K29= | Silent (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
- SRRM2 | c.4437A>G p.E1479= | Silent (SNP) | VAF 45/342 reads (13%) | called by muse, mutect2, varscan2
- STXBP2 | c.1671C>T p.T557= | Silent (SNP) | VAF 165/321 reads (51%) | catalogued as rs750599225, COSV99656836; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- STXBP5 | c.2001C>T p.G667= | Silent (SNP) | VAF 44/270 reads (16%) | catalogued as rs748425578; called by muse, mutect2, varscan2
- TAF4 | c.1920G>A p.R640= | Silent (SNP) | VAF 124/249 reads (50%) | called by muse, mutect2, varscan2
- TBCEL | c.546A>C p.T182= | Silent (SNP) | VAF 56/258 reads (22%) | called by muse, mutect2, varscan2
- TRDN | c.2118C>T p.F706= | Silent (SNP) | VAF 50/198 reads (25%) | called by muse, mutect2, varscan2
- UNCX | c.720C>T p.G240= | Silent (SNP) | VAF 67/332 reads (20%) | catalogued as COSV100310284; called by muse, mutect2, varscan2
- USH2A | c.2160C>T p.N720= | Silent (SNP) | VAF 32/225 reads (14%) | catalogued as rs1383328052, COSV104407717; called by muse, mutect2, varscan2
- WDR59 | c.361C>T p.L121= | Silent (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
- ZNF37A | c.672C>T p.F224= | Silent (SNP) | VAF 64/201 reads (32%) | called by muse, mutect2, varscan2
- ZNF862 | c.3126G>A p.G1042= | Silent (SNP) | VAF 83/361 reads (23%) | called by muse, mutect2, varscan2
- CCDC149 | c.63+17799G>A | Intron (SNP) | VAF 65/328 reads (20%) | catalogued as rs896749382, COSV100164814; called by mutect2, varscan2
- DCHS2 | n.2251_2252del | RNA (DEL) | VAF 78/219 reads (36%) | called by mutect2, pindel, varscan2
- PRR30 | c.*28C>T | 3'UTR (SNP) | VAF 97/639 reads (15%) | catalogued as rs1206684390; called by muse, varscan2
- RIMS1 | c.1679-16578G>T | Intron (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6305C>T | Intron (SNP) | VAF 93/589 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+4980T>A | Intron (SNP) | VAF 76/247 reads (31%) | called by muse, mutect2, varscan2
